Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6WD, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6WD-01A (Primary Tumor).

Neuropathology

Patient:
B-Day:
Patho-No.:

ICD-C-3
Oligodendroglioma, grade III
94511
Site: Brain, supratentorial NBS
C71.0
JW 8/12/13

Commentary:

Because of small foci with increased density and mitotic activity this otherwise well differentiated tumor is graded anaplastic oligodendroglioma WHO grade III.

Diagnosis:

Anaplastic oligodendroglioma WHO grade III

Untranslated full report
is housed at the BCR

Source: NCI Genomic Data Commons file 8f8b4b9a-b873-4b6c-8e6c-796e8ea99537 (TCGA-S9-A6WD.5F24A61F-39AA-426A-89D2-03205E9563D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).